Somatic mutation profile of tumor specimen 0DLIFQ from CCDI case PBBZKS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.0 years (3,659 days).
Specimen 0DLIFQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8716e58f-ec48-4dfa-aef0-8144fd2a5e40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLIFA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b95439cb-ac43-4e2e-bcf5-79633da51c4b

The open-access MAF lists 489 somatic variants for this specimen: 300 protein-altering or splice-affecting, 125 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 262, Silent 125, Intron 28, 3'UTR 24, Nonsense Mutation 18, Splice Region 10, Frame Shift Del 7, 5'UTR 6, Splice Site 2, 3'Flank 2, 5'Flank 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 173/373 reads (46%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- KIF11 | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 231/914 reads (25%) | catalogued as rs387906641, CM121125, COSV53271579; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PDGFRA | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 476/1100 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV57265219, COSV57268286, COSV57271923; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 395/1076 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 365/951 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 287/750 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 249/640 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs767041217; called by muse, mutect2, varscan2
- AARS2 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 35/658 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766485554, COSV55116456; called by muse, mutect2
- ABCA13 | c.14726C>T p.A4909V | Missense Mutation (SNP) | VAF 624/1425 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.107); catalogued as rs142771782; called by muse, mutect2, varscan2
- ABHD15 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 417/1044 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs754905589; called by muse, mutect2, varscan2
- ABI2 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 319/690 reads (46%) | catalogued as rs1160939828; called by muse, mutect2, varscan2
- ACACB | c.4877G>A p.R1626H | Missense Mutation (SNP) | VAF 320/775 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs762757492, COSV58140042; called by muse, mutect2, varscan2
- ACOT11 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 239/553 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.024); catalogued as rs776552244, COSV59350996; called by muse, mutect2, varscan2
- ACSBG1 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 228/580 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.104); catalogued as rs781699204; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 248/667 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.5); catalogued as rs143643823; called by muse, mutect2, varscan2
- ADAMTS14 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 229/817 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs114392999; called by muse, mutect2, varscan2
- ADARB2 | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 213/520 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1214688837, COSV101186678; called by muse, mutect2, varscan2
- ADGRG6 | c.3420A>G p.S1140= | Splice Region (SNP) | VAF 321/813 reads (39%) | catalogued as rs1369964387, COSV51591779; called by muse, mutect2, varscan2
- ADSS1 | c.262G>A p.G88S | Missense Mutation (SNP) | VAF 153/429 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs755041450; called by muse, mutect2, varscan2
- ADSS1 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 24/445 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.847); catalogued as rs999498738, COSV58276014; called by muse, mutect2
- AFAP1L1 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 221/602 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs777310262, COSV57046106; called by muse, mutect2, varscan2
- AGRN | c.2306C>T p.T769M | Missense Mutation (SNP) | VAF 265/656 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.216); catalogued as rs148837216; ClinVar: uncertain significance; called by muse, varscan2
- AHCYL1 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 28/1026 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1257309690; called by muse, mutect2
- AHI1 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 494/1069 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs192524061, COSV55631489; called by muse, varscan2
- AK1 | c.8-4G>A | Splice Region (SNP) | VAF 217/537 reads (40%) | catalogued as rs374460965; called by muse, mutect2, varscan2
- ALK | c.4294C>T p.R1432W | Missense Mutation (SNP) | VAF 195/470 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as COSV101202912; called by muse, mutect2, varscan2
- ANKAR | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 222/609 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1398199707; called by muse, mutect2, varscan2
- ANKRD13A | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 381/960 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs766253422, COSV55677069; called by muse, mutect2, varscan2
- AP3D1 | c.1979C>T p.A660V | Missense Mutation (SNP) | VAF 248/644 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as rs374995503; called by muse, mutect2, varscan2
- ARAP3 | c.3677G>A p.R1226Q | Missense Mutation (SNP) | VAF 252/573 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as rs779573946, COSV99500178; called by muse, mutect2, varscan2
- ARFGEF1 | c.5014C>T p.R1672C | Missense Mutation (SNP) | VAF 310/827 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1310875470; called by muse, mutect2, varscan2
- ARMH3 | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 327/631 reads (52%) | SIFT tolerated (0.63); PolyPhen benign (0.145); catalogued as rs752261708; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 380/1004 reads (38%) | catalogued as rs753865255; called by mutect2, varscan2
- ATXN2L | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 283/743 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57365138; called by muse, mutect2, varscan2
- BCL2L1 | c.647C>T p.T216M (on ENST00000307677 / NM_001317919.2; = p.T153M on NM_001191.4) | Missense Mutation (SNP) | VAF 344/902 reads (38%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.622); catalogued as rs1447088802, COSV56967574; called by muse, mutect2, varscan2
- BMP1 | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 228/559 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs371320295; called by muse, mutect2, varscan2
- BOLL | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 155/384 reads (40%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.887); catalogued as rs753383912, COSV56577996; called by muse, mutect2, varscan2
- C1QTNF2 | c.733G>A p.D245N (on ENST00000393975; = p.D200N on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 216/499 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs752487351, COSV67432497; called by muse, mutect2, varscan2
- C3 | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 31/1014 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV55577116; called by muse, mutect2
- C3orf20 | c.1732G>T p.E578* | Nonsense Mutation (SNP) | VAF 200/797 reads (25%) | catalogued as COSV99514206, COSV99514310; called by muse, mutect2, varscan2
- CACNA1H | c.4165G>A p.A1389T | Missense Mutation (SNP) | VAF 253/604 reads (42%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.988); catalogued as rs758458100; called by muse, mutect2, varscan2
- CAPN10 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 115/269 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0.059); catalogued as rs752063033; called by muse, mutect2, varscan2
- CAPRIN1 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 382/960 reads (40%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.464); catalogued as rs1309720008; called by muse, mutect2, varscan2
- CARD9 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 212/519 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.057); catalogued as rs139295959; called by muse, mutect2, varscan2
- CARNS1 | c.2267G>A p.R756H | Missense Mutation (SNP) | VAF 331/802 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.197); catalogued as rs766432094, COSV57054049; called by muse, mutect2, varscan2
- CBFA2T2 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 284/777 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs763801681; called by muse, mutect2, varscan2
- CBX6 | c.1108G>A p.V370I | Missense Mutation (SNP) | VAF 108/280 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as rs1450706739, COSV53321007; called by muse, mutect2, varscan2
- CCDC114 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 220/528 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as rs149194036; called by muse, mutect2, varscan2
- CCDC88B | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 54/611 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100105684; called by muse, mutect2
- CDH23 | c.3143G>A p.R1048H | Missense Mutation (SNP) | VAF 46/516 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs747839724, COSV54930498; called by muse, mutect2
- CDHR4 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 206/846 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772261307; called by muse, mutect2, varscan2
- CDHR5 | c.2389G>A p.V797M (on ENST00000358353 / NM_001171968.2; = p.V803M on NM_021924.5) | Missense Mutation (SNP) | VAF 22/418 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs775311797; called by muse, mutect2
- CDK8 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 256/371 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV67420297; called by muse, mutect2, varscan2
- CENPC | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 337/796 reads (42%) | catalogued as rs1189505436; called by muse, mutect2, varscan2
- CGN | c.1312C>T p.R438* | Nonsense Mutation (SNP) | VAF 341/966 reads (35%) | catalogued as rs367919390; called by muse, mutect2, varscan2
- CHEK2 | c.1345C>T p.R449C (on ENST00000382580 / NM_001005735.2; = p.R406C on NM_007194.4) | Missense Mutation (SNP) | VAF 411/1074 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.089); catalogued as rs587782527, CM136261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHEK2 | c.1153G>A p.G385S (on ENST00000382580 / NM_001005735.2; = p.G342S on NM_007194.4) | Missense Mutation (SNP) | VAF 392/1001 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs730881705; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CIC | c.4660G>A p.A1554T | Missense Mutation (SNP) | VAF 93/170 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as rs762480443; called by muse, mutect2, varscan2
- CILP | c.3055C>T p.R1019C | Missense Mutation (SNP) | VAF 215/528 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); catalogued as rs146484784; called by muse, mutect2, varscan2
- COL7A1 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 348/617 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs767174168; called by muse, mutect2, varscan2
- CPNE6 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 153/375 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs771034745, COSV53744935; called by muse, mutect2, varscan2
- CPT1C | c.2003C>T p.S668L | Missense Mutation (SNP) | VAF 328/866 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1378344393; called by muse, mutect2, varscan2
- CRACD | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 259/634 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs1167140878; called by muse, mutect2, varscan2
- CRB2 | c.3229G>A p.A1077T | Missense Mutation (SNP) | VAF 99/238 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.15); catalogued as rs897580232; called by muse, mutect2, varscan2
- CRTAC1 | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 290/521 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs755410645, COSV54004200; called by muse, mutect2, varscan2
- CRTC3 | c.1780G>A p.G594R | Missense Mutation (SNP) | VAF 243/594 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753851768; called by muse, mutect2, varscan2
- CTSA | c.1089-6C>T | Splice Region (SNP) | VAF 164/396 reads (41%) | catalogued as rs775108835; called by muse, mutect2, varscan2
- CTU1 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 130/343 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1422294103, COSV99081504; called by muse, mutect2, varscan2
- CUX2 | c.1594G>A p.G532S | Missense Mutation (SNP) | VAF 191/462 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs747736165, COSV55632860; called by muse, mutect2, varscan2
- CYC1 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 247/677 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781559773; called by muse, mutect2, varscan2
- CYHR1 | c.247-4G>A | Splice Region (SNP) | VAF 104/285 reads (36%) | catalogued as rs760402762; called by muse, mutect2, varscan2
- CYP2W1 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 190/473 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.881); catalogued as rs749977172, COSV58270203, COSV58271612; called by muse, mutect2, varscan2
- DCST2 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 230/603 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs373815194; called by muse, mutect2, varscan2
- DLEC1 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 336/639 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs200156259; called by muse, mutect2, varscan2
- DLGAP2 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 50/1096 reads (5%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.007); catalogued as rs1356764415, COSV101421527; called by muse, mutect2
- DMAP1 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 364/817 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1200185487; called by muse, mutect2, varscan2
- DNAH7 | c.4513G>A p.V1505M | Missense Mutation (SNP) | VAF 357/926 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765322204, COSV56791620; called by muse, mutect2, varscan2
- DOCK2 | c.4511C>T p.T1504M | Missense Mutation (SNP) | VAF 334/949 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs201320169, COSV56944226; called by muse, mutect2, varscan2
- DOCK6 | c.5395G>A p.V1799I | Missense Mutation (SNP) | VAF 199/578 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs936790178; called by muse, mutect2, varscan2
- DPP9 | c.2194G>A p.G732R (on ENST00000598800; = p.G761R on NM_139159.5) | Missense Mutation (SNP) | VAF 135/305 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752410065, COSV53589033; called by muse, mutect2, varscan2
- DST | c.19187C>T p.T6396M (on ENST00000361203 / NM_001374722.1; = p.T4093M on NM_015548.5) | Missense Mutation (SNP) | VAF 463/1037 reads (45%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.637); catalogued as rs373240529; called by muse, mutect2, varscan2
- DUSP14 | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 238/646 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.153); catalogued as rs775016737; called by muse, mutect2, varscan2
- DVL1 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 157/361 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.2); catalogued as rs575043209, COSV66679237; called by muse, mutect2, varscan2
- ELANE | c.67+1del | Frame Shift Del (DEL) | VAF 206/510 reads (40%) | catalogued as rs886039350; ClinVar: uncertain significance; called by mutect2, varscan2
- FAM118A | c.1035del p.K345Nfs*23 | Frame Shift Del (DEL) | VAF 402/930 reads (43%) | catalogued as rs1356118949; called by mutect2, varscan2
- FAM160A2 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 201/485 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV56415055; called by muse, mutect2, varscan2
- FAM50A | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 364/1014 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557200364, COSV50131047; called by muse, mutect2, varscan2
- FAT4 | c.13406C>T p.A4469V | Missense Mutation (SNP) | VAF 377/907 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.987); catalogued as rs1447370410; called by muse, mutect2, varscan2
- FBH1 | c.2278C>T p.R760W (on ENST00000362091 / NM_178150.3; = p.R811W on NM_032807.4) | Missense Mutation (SNP) | VAF 325/883 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1476324073, COSV62981901; called by muse, mutect2, varscan2
- FBXO10 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 53/1548 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52833761; called by muse, mutect2
- FBXO31 | c.1495G>A p.V499I | Missense Mutation (SNP) | VAF 185/515 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs562737163, COSV100291225; called by muse, mutect2, varscan2
- FMNL3 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 244/596 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs777311087, COSV53298022; called by muse, mutect2, varscan2
- FOXN1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 238/605 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.366); catalogued as rs142248984; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXRED2 | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 309/835 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.517); catalogued as rs202049182, COSV99340854; called by muse, mutect2, varscan2
- GALNTL6 | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 232/649 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72494153; called by muse, mutect2, varscan2
- GBA | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 94/1087 reads (9%) | catalogued as CM016030, COSV59169914; called by muse, mutect2
- GJA1 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 205/433 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as CM095018, COSV56997932; called by muse, mutect2, varscan2
- GJD2 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 317/730 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs1278333715, COSV51749385; called by muse, mutect2, varscan2
- GNB4 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 330/1061 reads (31%) | catalogued as rs1252790676, COSV51709431; called by muse, mutect2
- GNGT2 | c.84G>A p.P28= | Splice Region (SNP) | VAF 143/408 reads (35%) | catalogued as rs199593250; called by muse, mutect2, varscan2
- GPNMB | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 400/1071 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs758091301, COSV51697487; called by muse, mutect2, varscan2
- GPRIN2 | c.1147C>T p.R383* | Nonsense Mutation (SNP) | VAF 162/1160 reads (14%) | catalogued as rs376858389; called by muse, mutect2, varscan2
- GREB1 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 412/1122 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs779801498, COSV52192671; called by muse, mutect2, varscan2
- GREB1L | c.2984C>T p.P995L | Missense Mutation (SNP) | VAF 230/673 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376272319, COSV52557578; called by muse, mutect2, varscan2
- GRHL1 | c.1429G>A p.V477M | Missense Mutation (SNP) | VAF 549/1375 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs751933053; called by muse, mutect2, varscan2
- GUSB | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 91/340 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs780835314, COSV100512811; called by muse, varscan2
- HCK | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 227/676 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764149571; called by muse, mutect2, varscan2
- HDAC1 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 56/723 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as rs1427903376, COSV65190786; called by muse, mutect2
- HECA | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 336/814 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as rs1245674126; called by muse, varscan2
- HERC1 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 323/810 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs769145958, COSV71250686; called by muse, mutect2, varscan2
- HIP1 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 85/880 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as rs587639717; called by muse, mutect2
- IGSF9B | c.2255G>A p.R752H | Missense Mutation (SNP) | VAF 293/777 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.15); catalogued as rs768469068, COSV58064347; called by muse, mutect2, varscan2
- IL17REL | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 28/942 reads (3%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs1340182755; called by muse, mutect2
- INSC | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 349/825 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs368344814; called by muse, mutect2, varscan2
- INSL3 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 179/475 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs998261923, COSV100427645; called by muse, mutect2, varscan2
- IQGAP3 | c.4222C>T p.R1408C | Missense Mutation (SNP) | VAF 167/424 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1263593520; called by muse, mutect2, varscan2
- ITGA7 | c.3371C>T p.A1124V (on ENST00000555728; = p.A1080V on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 341/832 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs201977360, COSV57692534; called by muse, mutect2, varscan2
- ITPR3 | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 314/822 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1324375924; called by muse, mutect2, varscan2
- KANK2 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 146/401 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs537320085; called by muse, mutect2, varscan2
- KANSL2 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 317/830 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.426); catalogued as rs775198681; called by muse, mutect2, varscan2
- KAT2B | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 499/1024 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs200572606; called by muse, mutect2, varscan2
- KDM2B | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 28/1025 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.948); catalogued as rs368219190, COSV100997292; called by muse, mutect2
- KDM3B | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 253/633 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as rs759653444, COSV58687393; called by muse, mutect2, varscan2
- KDM7A | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 189/674 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs1451814847, COSV99134070; called by muse, mutect2, varscan2
- KLF15 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 179/408 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1053425534; called by muse, mutect2, varscan2
- KRT14 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 210/496 reads (42%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.862); catalogued as rs779340321; called by mutect2, varscan2
- KRT31 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 35/818 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs766304221, COSV52433276; called by muse, mutect2
- LAMB4 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 202/701 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs751482652, COSV104391500, COSV52715777; called by muse, mutect2, varscan2
- LAPTM4B | c.815G>A p.R272Q (on ENST00000445593; = p.R181Q on NM_018407.6) | Missense Mutation (SNP) | VAF 207/521 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs147058372; called by muse, mutect2, varscan2
- LATS2 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 160/199 reads (80%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV66875455; called by muse, mutect2, varscan2
- LIMK1 | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 22/536 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs535891232; called by muse, mutect2
- LRP2 | c.3068C>T p.T1023I | Missense Mutation (SNP) | VAF 306/662 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs776970596, COSV99788019; called by muse, mutect2, varscan2
- LRRIQ4 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 145/379 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as rs371657729; called by muse, mutect2, varscan2
- LSS | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 189/477 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139587765; called by muse, mutect2, varscan2
- MBD5 | c.1327G>A p.V443M | Missense Mutation (SNP) | VAF 177/535 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs137977565, CM1212426, COSV68696144; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MCM6 | c.1708G>A p.D570N | Missense Mutation (SNP) | VAF 353/802 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs765559970; called by muse, mutect2, varscan2
- MCOLN1 | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 108/281 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747683527, COSV51173977; called by muse, mutect2, varscan2
- MCTP1 | c.2034G>A p.T678= | Splice Region (SNP) | VAF 304/776 reads (39%) | catalogued as rs201808520, COSV56524563; called by muse, mutect2, varscan2
- MPDZ | c.3139C>T p.R1047W | Missense Mutation (SNP) | VAF 290/760 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772690542, COSV59922471; called by muse, mutect2, varscan2
- MROH1 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 216/552 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as rs1328220205; called by muse, mutect2, varscan2
- MRPL24 | c.5G>A p.R2H | Missense Mutation (SNP) | VAF 27/975 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1200549899, COSV61978037; called by muse, mutect2
- MYH6 | c.2087G>A p.R696H | Missense Mutation (SNP) | VAF 352/933 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs757728653, COSV62450095; called by muse, mutect2, varscan2
- MYO10 | c.4106C>T p.P1369L | Missense Mutation (SNP) | VAF 492/1070 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs370082246; called by muse, mutect2, varscan2
- NACAD | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 125/362 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs1175364114; called by muse, varscan2
- NIPA1 | c.901G>A p.V301I | Missense Mutation (SNP) | VAF 287/745 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.403); catalogued as rs561618931, COSV61680719; called by muse, mutect2, varscan2
- NMRK2 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 132/335 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs760778323; called by muse, mutect2, varscan2
- NOS2 | c.2405G>A p.R802H | Missense Mutation (SNP) | VAF 214/522 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs774982047, COSV58223772; called by muse, mutect2, varscan2
- NRK | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 37/1462 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1450962402, COSV54606610; called by muse, mutect2
- NSF | c.1547G>A p.R516Q | Missense Mutation (SNP) | VAF 449/1060 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs761257406; called by muse, mutect2, varscan2
- NUB1 | c.990del p.K330Nfs*2 | Frame Shift Del (DEL) | VAF 260/832 reads (31%) | catalogued as rs760102115; called by mutect2, varscan2
- NXN | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 197/580 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs780435566, COSV61094859; called by muse, mutect2, varscan2
- OBSCN | c.12629G>A p.R4210Q | Missense Mutation (SNP) | VAF 127/259 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs766787288, COSV52762427; called by muse, mutect2, varscan2
- ODF3 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 163/432 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs149763715; called by muse, mutect2, varscan2
- OR52K1 | c.236C>T p.T79M | Missense Mutation (SNP) | VAF 294/828 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs201104279; called by muse, mutect2, varscan2
- OSBPL8 | c.2158C>T p.R720W | Missense Mutation (SNP) | VAF 394/1091 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1366794081; called by muse, mutect2, varscan2
- OVCH2 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 278/788 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750962963; called by muse, mutect2, varscan2
- PAF1 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 312/824 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as rs1233362615, COSV99655659; called by muse, mutect2, varscan2
- PALMD | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 360/941 reads (38%) | catalogued as rs942857815; called by muse, mutect2, varscan2
- PCBP2 | c.914G>A p.R305H (on ENST00000439930 / NM_001128911.2; = p.R306H on NM_005016.6) | Missense Mutation (SNP) | VAF 278/758 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV63727838; called by muse, mutect2, varscan2
- PCDH1 | c.1723C>T p.R575W | Missense Mutation (SNP) | VAF 270/656 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs374252625; called by muse, mutect2, varscan2
- PCGF2 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 371/949 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as rs746360625; called by muse, mutect2, varscan2
- PCSK4 | c.1403C>T p.P468L | Missense Mutation (SNP) | VAF 145/369 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as rs778010643, COSV56301805; called by muse, mutect2, varscan2
- PDCD6IP | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 257/564 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs772750136; called by muse, mutect2, varscan2
- PDE7B | c.1178C>T p.T393M | Missense Mutation (SNP) | VAF 238/673 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.833); catalogued as COSV57494552; called by muse, mutect2, varscan2
- PER1 | c.2152G>A p.V718I | Missense Mutation (SNP) | VAF 194/505 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199563583, COSV57919074; called by muse, mutect2, varscan2
- PHF24 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 327/860 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs751258396, COSV54274856; called by muse, mutect2, varscan2
- PI4KA | c.4303C>T p.R1435W | Missense Mutation (SNP) | VAF 163/436 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV99745266; called by muse, mutect2, varscan2
- PIEZO1 | c.2165C>T p.P722L | Missense Mutation (SNP) | VAF 209/505 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1223247493; called by muse, mutect2, varscan2
- PIGL | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 348/963 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750654333, COSV56684004; called by muse, mutect2, varscan2
- PLCG1 | c.3734G>A p.R1245Q (on ENST00000373271 / NM_182811.2; = p.R1246Q on NM_002660.3) | Missense Mutation (SNP) | VAF 336/768 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs750042405; called by muse, varscan2
- PLCL2 | c.1969G>A p.A657T (on ENST00000615277 / NM_001144382.2; = p.A531T on NM_015184.5) | Missense Mutation (SNP) | VAF 159/703 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.643); catalogued as rs200999126, COSV101196826; called by muse, mutect2, varscan2
- PNP | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 286/724 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139364283; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR3D | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 377/917 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as rs772987150; called by muse, mutect2, varscan2
- POLRMT | c.2755G>A p.V919I | Missense Mutation (SNP) | VAF 123/328 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.386); catalogued as rs78517836, COSV99241067; called by muse, mutect2, varscan2
- POR | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 137/284 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs782805067; called by muse, mutect2, varscan2
- PPFIA4 | c.1403G>A p.R468Q | Missense Mutation (SNP) | VAF 363/914 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs776719712; called by muse, mutect2, varscan2
- PPP5C | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 250/637 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as rs1261779030, COSV50140979; called by muse, mutect2, varscan2
- PRPF40A | c.2663G>A p.R888H | Missense Mutation (SNP) | VAF 410/1050 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs779982217; called by muse, varscan2
- PRRX2 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 50/572 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs748715547; called by muse, mutect2
- PRSS36 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 228/509 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs753254141; called by muse, mutect2, varscan2
- PSMD5 | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 400/883 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as rs537650288; called by muse, mutect2, varscan2
- PSMD6 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 280/577 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as rs535986103; called by muse, mutect2, varscan2
- PTDSS2 | c.1172C>T p.T391M | Missense Mutation (SNP) | VAF 105/560 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1312154533; called by muse, mutect2, varscan2
- RAB11FIP3 | c.971C>T p.T324M | Missense Mutation (SNP) | VAF 43/504 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs766981935; called by muse, mutect2
- RAET1E | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 497/1202 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.148); catalogued as rs975723762; called by muse, mutect2, varscan2
- RANBP10 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 318/852 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.744); catalogued as rs776492991, COSV58156753; called by muse, mutect2, varscan2
- RGPD3 | c.3683C>T p.A1228V | Missense Mutation (SNP) | VAF 97/367 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as rs938928799; called by muse, mutect2, varscan2
- RIPOR2 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 347/957 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs373238039, COSV99428765; called by muse, mutect2, varscan2
- ROCK2 | c.3169C>T p.R1057W | Missense Mutation (SNP) | VAF 506/1213 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59955534; called by muse, mutect2, varscan2
- RUNX1 | c.668G>A p.R223H (on ENST00000344691 / NM_001001890.3; = p.R250H on NM_001754.5) | Missense Mutation (SNP) | VAF 272/716 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs771614642, COSV55881639, COSV55890164; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.12719C>T p.T4240M | Missense Mutation (SNP) | VAF 236/644 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); catalogued as COSV63714535; called by muse, mutect2, varscan2
- SALL3 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 30/1174 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs759085561, COSV73305862; called by muse, mutect2
- SCAP | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 222/430 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs879008440; called by muse, mutect2, varscan2
- SCN2B | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 44/956 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54050422, COSV54050942; called by muse, mutect2
- SEMA4D | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 222/539 reads (41%) | SIFT tolerated (0.74); PolyPhen benign (0.232); catalogued as rs910535413, COSV59391543; called by muse, mutect2, varscan2
- SGO2 | c.1943del p.F648Sfs*14 | Frame Shift Del (DEL) | VAF 285/559 reads (51%) | catalogued as rs771387868; called by mutect2, varscan2
- SHPRH | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 470/1228 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs1433044914, COSV51609814; called by muse, mutect2, varscan2
- SHROOM2 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 201/479 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760130171, COSV66608289; called by muse, mutect2, varscan2
- SLC12A7 | c.3040G>A p.V1014I | Missense Mutation (SNP) | VAF 371/927 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as rs376924487; called by muse, mutect2, varscan2
- SLC1A4 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 460/1216 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs142803009; called by muse, varscan2
- SLC26A11 | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 501/1222 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371059198; called by muse, mutect2, varscan2
- SLC27A5 | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 287/770 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs781015923; called by muse, mutect2, varscan2
- SLC38A10 | c.509T>G p.L170R | Missense Mutation (SNP) | VAF 350/900 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751039909; called by muse, mutect2, varscan2
- SLC6A7 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 327/787 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs138255265; called by muse, mutect2, varscan2
- SRGAP2 | c.980G>A p.R327H (on ENST00000624873 / NM_001170637.4; = p.R328H on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs781783401, COSV99832752; called by mutect2, varscan2
- SSC5D | c.1212C>T p.D404= | Splice Region (SNP) | VAF 163/438 reads (37%) | catalogued as rs1568476114, COSV67476624, COSV67476799; called by muse, mutect2, varscan2
- STARD9 | c.13915C>T p.R4639C | Missense Mutation (SNP) | VAF 412/935 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1044297137; called by muse, mutect2, varscan2
- SYT3 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 296/758 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.019); catalogued as rs766161130; called by mutect2, varscan2
- TAF1C | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 206/576 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs538394488; called by muse, mutect2, varscan2
- TAX1BP3 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 475/1152 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs117575113; called by muse, mutect2, varscan2
- TBC1D9B | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 213/608 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs557171304; called by muse, mutect2, varscan2
- TCF20 | c.3065G>A p.R1022Q | Missense Mutation (SNP) | VAF 157/333 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV59488179; called by muse, mutect2, varscan2
- TEKT4 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 202/518 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs782046554, COSV54623213; called by muse, mutect2, varscan2
- TENT2 | c.580+1G>A p.X194_splice | Splice Site (SNP) | VAF 378/861 reads (44%) | catalogued as rs1294717408, COSV99706469; called by muse, mutect2, varscan2
- TFAP4 | c.354+4C>T | Splice Region (SNP) | VAF 127/311 reads (41%) | catalogued as COSV52597209; called by muse, mutect2, varscan2
- THAP4 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 386/809 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs778875819, COSV67191312; called by muse, mutect2
- THEMIS2 | c.1117C>T p.R373W | Missense Mutation (SNP) | VAF 147/344 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs535519556; called by muse, mutect2, varscan2
- TJP1 | c.4621C>T p.R1541C | Missense Mutation (SNP) | VAF 303/741 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as rs1391332490, COSV100632756; called by muse, mutect2, varscan2
- TLE3 | c.2107G>A p.V703M | Missense Mutation (SNP) | VAF 255/743 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1200413578, COSV58173997; called by muse, mutect2, varscan2
- TMEM266 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 222/578 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as rs760576380; called by muse, mutect2, varscan2
- TMEM63C | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 235/611 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs756640588, COSV100029762; called by muse, mutect2, varscan2
- TMEM94 | c.1861G>A p.V621M | Missense Mutation (SNP) | VAF 292/790 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs374436256; called by muse, mutect2, varscan2
- TNFRSF1B | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 264/665 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs969055764, COSV104426561; called by muse, mutect2, varscan2
- TSEN54 | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 212/555 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.238); catalogued as rs572964665; called by muse, mutect2, varscan2
- TTN | c.70315C>T p.R23439W (on ENST00000591111; = p.R16015W on NM_003319.4) | Missense Mutation (SNP) | VAF 252/629 reads (40%) | PolyPhen probably damaging (0.999); catalogued as rs1370877041; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUFM | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 185/474 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs779228479, COSV57948554, COSV57949231; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBE2E2 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 151/527 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.489); catalogued as COSV100232616; called by muse, mutect2, varscan2
- VARS1 | c.2839C>T p.R947C | Missense Mutation (SNP) | VAF 370/860 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1347491282; called by muse, mutect2, varscan2
- VAT1L | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 423/978 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); catalogued as rs764373444, COSV56816049, COSV56817510; called by muse, mutect2, varscan2
- WFS1 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 174/469 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs779791068, COSV56990863; called by muse, mutect2, varscan2
- YARS2 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 421/1099 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs200280315; called by muse, mutect2, varscan2
- ZBTB34 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 34/976 reads (3%) | SIFT tolerated (0.78); PolyPhen benign (0.042); catalogued as rs1421571479; called by muse, mutect2
- ZBTB7B | c.670C>T p.P224S (on ENST00000292176; = p.P258S on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 320/694 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs773495689; called by muse, mutect2, varscan2
- ZFYVE26 | c.3220G>A p.E1074K | Missense Mutation (SNP) | VAF 366/875 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as rs773193290; called by muse, mutect2, varscan2
- ZNF408 | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 161/386 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs771251935; called by muse, mutect2, varscan2
- ZNF445 | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 256/519 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs781553960, COSV104432426, COSV68539768; called by muse, mutect2, varscan2
- ZNF469 | c.11179G>A p.G3727R (on ENST00000437464; = p.G3755R on NM_001367624.2) | Missense Mutation (SNP) | VAF 167/455 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.867); catalogued as rs548347344; called by muse, mutect2, varscan2
- ZNF536 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 170/397 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs896581213, COSV62821835; called by muse, mutect2, varscan2
- ZNF557 | c.1247C>T p.T416M (on ENST00000414706 / NM_001044388.2; = p.T423M on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 219/522 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs747902079, COSV53273523; called by muse, mutect2, varscan2
- ZNF628 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 106/248 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs755715368; called by muse, mutect2, varscan2
- ZNF662 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 324/683 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs145624827; called by muse, mutect2, varscan2
- ZNF845 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 169/414 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs562879062; called by muse, mutect2, varscan2
- ZP1 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 183/481 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs769067635, COSV99612414; called by muse, mutect2, varscan2
- ACTC1 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 39/1038 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2
- ALAS1 | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 293/652 reads (45%) | called by muse, mutect2, varscan2
- AS3MT | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 227/799 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- ASMT | c.581C>T p.A194V (on ENST00000381229; = p.A222V on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 392/1014 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ATG7 | c.883A>G p.S295G | Missense Mutation (SNP) | VAF 20/620 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- ATRX | c.5772del p.D1925Mfs*30 | Frame Shift Del (DEL) | VAF 264/666 reads (40%) | called by mutect2, varscan2
- C8G | c.556+2T>C p.X186_splice | Splice Site (SNP) | VAF 202/481 reads (42%) | called by muse, mutect2, varscan2
- CA5A | c.394C>A p.H132N | Missense Mutation (SNP) | VAF 265/720 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CAPN5 | c.2003C>T p.A668V (on ENST00000456580; = p.A628V on NM_004055.5) | Missense Mutation (SNP) | VAF 237/682 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CDCA2 | c.390C>A p.G130= | Splice Region (SNP) | VAF 29/764 reads (4%) | called by muse, mutect2
- CHST3 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 16/377 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.012); called by muse, mutect2
- CLCA1 | c.2431A>G p.T811A | Missense Mutation (SNP) | VAF 366/935 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNOT1 | c.5440C>T p.R1814* | Nonsense Mutation (SNP) | VAF 465/1192 reads (39%) | called by muse, mutect2, varscan2
- CRYGS | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 321/901 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DMXL1 | c.1328G>A p.G443D | Missense Mutation (SNP) | VAF 342/896 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPG5 | c.7459C>T p.R2487* | Nonsense Mutation (SNP) | VAF 166/435 reads (38%) | called by muse, mutect2, varscan2
- ESRP2 | c.711-7T>C | Splice Region (SNP) | VAF 228/508 reads (45%) | called by muse, mutect2, varscan2
- EYS | c.4798A>C p.M1600L | Missense Mutation (SNP) | VAF 364/905 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- FAT1 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 311/813 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FOXM1 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 463/1092 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FZD1 | c.1132C>T p.R378* | Nonsense Mutation (SNP) | VAF 144/446 reads (32%) | called by muse, mutect2, varscan2
- GPR6 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 172/407 reads (42%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- HIVEP1 | c.3733C>T p.R1245* | Nonsense Mutation (SNP) | VAF 306/844 reads (36%) | called by muse, mutect2, varscan2
- KLHL8 | c.1513C>T p.L505F | Missense Mutation (SNP) | VAF 270/685 reads (39%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KNDC1 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 60/241 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LTBP1 | c.4895A>G p.E1632G (on ENST00000404816 / NM_206943.4; = p.E1306G on NM_000627.4) | Missense Mutation (SNP) | VAF 416/1050 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MARS1 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 194/520 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- MCOLN3 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 343/905 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- MMS19 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 315/590 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MYH13 | c.3853C>T p.Q1285* | Nonsense Mutation (SNP) | VAF 399/969 reads (41%) | called by muse, mutect2, varscan2
- MYPN | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 21/335 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.058); called by muse, mutect2
- MYRF | c.2378C>T p.T793I (on ENST00000278836 / NM_001127392.3; = p.T784I on NM_013279.4) | Missense Mutation (SNP) | VAF 45/965 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.058); called by muse, mutect2
- PHF21A | c.703C>T p.R235* (on ENST00000418153 / NM_001101802.3; = p.R236* on NM_016621.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 206/422 reads (49%) | called by muse, mutect2, varscan2
- PTGER1 | c.967G>A p.G323S | Missense Mutation (SNP) | VAF 123/271 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- RASAL2 | c.811A>G p.T271A | Missense Mutation (SNP) | VAF 333/819 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- RD3 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 382/908 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.288); called by muse, mutect2
- RERE | c.3445C>A p.L1149M | Missense Mutation (SNP) | VAF 406/958 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- RNF20 | c.2279A>T p.N760I | Missense Mutation (SNP) | VAF 492/1252 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RNF34 | c.357G>T p.K119N | Missense Mutation (SNP) | VAF 397/941 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- ROBO1 | c.2929G>A p.A977T | Missense Mutation (SNP) | VAF 390/944 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- SALL3 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 213/454 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAR1A | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 234/971 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SETD1B | c.4765del p.Q1589Sfs*11 | Frame Shift Del (DEL) | VAF 52/123 reads (42%) | called by mutect2, varscan2
- SETD2 | c.6799_6812dup p.S2271Rfs*43 | Frame Shift Ins (INS) | VAF 176/460 reads (38%) | called by mutect2, varscan2
- SH3D21 | c.2117T>C p.L706P (on ENST00000453908 / NM_001162530.2; = p.L595P on NM_024676.5) | Missense Mutation (SNP) | VAF 199/507 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SIPA1L1 | c.5317C>T p.R1773* | Nonsense Mutation (SNP) | VAF 411/1026 reads (40%) | called by muse, mutect2, varscan2
- SKIDA1 | c.2685A>G p.I895M | Missense Mutation (SNP) | VAF 279/720 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- SMTNL2 | c.1305G>T p.M435I (on ENST00000389313 / NM_001114974.2; = p.M291I on NM_198501.3) | Missense Mutation (SNP) | VAF 36/642 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2
- STAC3 | c.514A>G p.N172D | Missense Mutation (SNP) | VAF 331/883 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TADA2B | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 24/842 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TSPAN6 | c.634G>A p.V212I | Missense Mutation (SNP) | VAF 415/1054 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- TYK2 | c.3172C>T p.R1058C | Missense Mutation (SNP) | VAF 428/995 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- UNC13A | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 256/709 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- VWA8 | c.2114C>T p.A705V | Missense Mutation (SNP) | VAF 30/626 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.04); called by muse, mutect2
- ZNF540 | c.1590G>T p.K530N | Missense Mutation (SNP) | VAF 28/748 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ZNF544 | c.1493G>T p.G498V | Missense Mutation (SNP) | VAF 210/507 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF852 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 316/639 reads (49%) | called by muse, mutect2, varscan2
- ABCA2 | c.2106C>T p.I702= (on ENST00000614293; = p.I672= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 132/409 reads (32%) | catalogued as rs1256038903, COSV99688046; called by muse, mutect2, varscan2
- ADAMTS5 | c.2163C>T p.C721= | Silent (SNP) | VAF 305/886 reads (34%) | catalogued as rs201435455; called by muse, mutect2, varscan2
- ANAPC15 | c.135G>A p.A45= | Silent (SNP) | VAF 293/720 reads (41%) | catalogued as rs138271743, COSV56194408; called by muse, mutect2, varscan2
- APC2 | c.6738C>T p.H2246= | Silent (SNP) | VAF 96/208 reads (46%) | called by muse, mutect2, varscan2
- APOBEC3B | c.432C>T p.R144= | Silent (SNP) | VAF 291/692 reads (42%) | catalogued as rs746114818; called by muse, mutect2, varscan2
- ASH1L | c.2454C>T p.D818= | Silent (SNP) | VAF 36/1534 reads (2%) | called by muse, mutect2
- ATG16L2 | c.1536C>T p.H512= | Silent (SNP) | VAF 303/709 reads (43%) | catalogued as rs772863057; called by muse, mutect2, varscan2
- AUTS2 | c.1290G>A p.P430= | Silent (SNP) | VAF 92/257 reads (36%) | catalogued as rs1457037255, COSV61428800; called by muse, mutect2, varscan2
- C1orf226 | c.627C>T p.D209= | Silent (SNP) | VAF 199/415 reads (48%) | catalogued as rs772635250; called by muse, mutect2, varscan2
- C3 | c.3786C>T p.Y1262= | Silent (SNP) | VAF 263/648 reads (41%) | catalogued as rs768299272; called by muse, mutect2, varscan2
- CABIN1 | c.1257G>A p.P419= | Silent (SNP) | VAF 179/464 reads (39%) | catalogued as rs370920994; called by muse, mutect2, varscan2
- CACNA1S | c.2562C>T p.Y854= | Silent (SNP) | VAF 429/1085 reads (40%) | catalogued as rs373510147; ClinVar: likely benign; called by muse, mutect2, varscan2
- CASKIN1 | c.3672G>A p.P1224= | Silent (SNP) | VAF 150/346 reads (43%) | catalogued as rs149465240; called by muse, mutect2, varscan2
- CCDC78 | c.1209C>T p.N403= | Silent (SNP) | VAF 226/570 reads (40%) | catalogued as rs563037365; called by muse, mutect2, varscan2
- CDC42BPB | c.4371G>A p.A1457= | Silent (SNP) | VAF 209/563 reads (37%) | catalogued as rs541329650, COSV63475208; called by muse, mutect2, varscan2
- CDH2 | c.1449C>T p.T483= | Silent (SNP) | VAF 227/561 reads (40%) | catalogued as rs760359051, COSV52300119; called by muse, mutect2, varscan2
- CDH8 | c.1224C>T p.S408= | Silent (SNP) | VAF 376/1023 reads (37%) | catalogued as rs531546217, COSV100182312, COSV54907616; called by muse, mutect2, varscan2
- CLUH | c.138G>A p.T46= (on ENST00000435359; = p.T84= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 287/695 reads (41%) | catalogued as rs200262545, COSV70929343; called by muse, mutect2, varscan2
- COL5A1 | c.1377G>A p.A459= | Silent (SNP) | VAF 260/742 reads (35%) | catalogued as rs746091599, COSV65672107; called by muse, mutect2, varscan2
- CREB5 | c.384C>T p.N128= (on ENST00000357727 / NM_182898.4; = p.N121= on NM_004904.3) | Silent (SNP) | VAF 235/629 reads (37%) | catalogued as rs199608009, COSV63217204; called by muse, mutect2, varscan2
- CRMP1 | c.531C>T p.S177= | Silent (SNP) | VAF 278/786 reads (35%) | catalogued as rs752133402, COSV61483722; called by muse, varscan2
- CSMD1 | c.6678G>A p.A2226= (on ENST00000520002; = p.A2225= on NM_033225.6) | Silent (SNP) | VAF 418/1024 reads (41%) | catalogued as rs750789091, COSV59338632, COSV59390505; called by muse, mutect2, varscan2
- CUL9 | c.6660C>T p.S2220= | Silent (SNP) | VAF 295/668 reads (44%) | catalogued as rs754697150, COSV52726054; called by muse, mutect2, varscan2
- CXCR2 | c.558C>T p.T186= | Silent (SNP) | VAF 190/390 reads (49%) | catalogued as rs201476763; called by muse, mutect2, varscan2
- CXXC4 | c.471T>C p.G157= | Silent (SNP) | VAF 172/502 reads (34%) | catalogued as rs775030831, COSV67296433; called by mutect2, varscan2
- CYFIP2 | c.1218C>T p.H406= | Silent (SNP) | VAF 248/626 reads (40%) | catalogued as rs1459779106; called by muse, mutect2, varscan2
- CYTH4 | c.558C>T p.Y186= | Silent (SNP) | VAF 301/739 reads (41%) | catalogued as rs148578667; called by muse, mutect2, varscan2
- DAZAP1 | c.420G>A p.T140= | Silent (SNP) | VAF 149/424 reads (35%) | catalogued as rs1024529709; called by muse, mutect2, varscan2
- DGKD | c.2601C>T p.F867= (on ENST00000264057 / NM_152879.3; = p.F823= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/146 reads (25%) | catalogued as rs140893534; called by muse, mutect2, varscan2
- EPPK1 | c.9615C>T p.D3205= | Silent (SNP) | VAF 45/291 reads (15%) | catalogued as rs1285721432; called by muse, mutect2, varscan2
- EPS15L1 | c.1509G>A p.S503= | Silent (SNP) | VAF 290/717 reads (40%) | catalogued as rs141695393; called by muse, mutect2, varscan2
- F13A1 | c.1236C>T p.P412= | Silent (SNP) | VAF 220/547 reads (40%) | catalogued as rs759699312; called by muse, mutect2, varscan2
- FAM160A1 | c.201C>T p.Y67= | Silent (SNP) | VAF 437/1118 reads (39%) | catalogued as rs568035952; called by muse, mutect2, varscan2
- FAP | c.720C>T p.G240= | Silent (SNP) | VAF 232/636 reads (36%) | catalogued as rs185593943, COSV51862569, COSV51864618; called by muse, mutect2, varscan2
- FAR1 | c.396G>A p.T132= | Silent (SNP) | VAF 386/974 reads (40%) | catalogued as rs146264671; called by muse, mutect2, varscan2
- FAT2 | c.2133C>A p.T711= | Silent (SNP) | VAF 227/611 reads (37%) | catalogued as COSV55819275; called by muse, mutect2, varscan2
- FCGBP | c.9327C>T p.D3109= | Silent (SNP) | VAF 132/604 reads (22%) | catalogued as rs144740210; called by mutect2, varscan2
- FCGBP | c.5724C>T p.D1908= | Silent (SNP) | VAF 60/518 reads (12%) | catalogued as rs1403190758; called by muse, mutect2, varscan2
- FCGRT | c.774C>T p.H258= | Silent (SNP) | VAF 120/368 reads (33%) | catalogued as rs758931615; called by mutect2, varscan2
- FRMD4B | c.2400G>A p.P800= | Silent (SNP) | VAF 293/726 reads (40%) | catalogued as rs555866791; called by muse, mutect2, varscan2
- GAK | c.597G>A p.S199= | Silent (SNP) | VAF 318/807 reads (39%) | catalogued as rs141049049; called by muse, mutect2, varscan2
- GAL3ST3 | c.624C>T p.D208= | Silent (SNP) | VAF 195/434 reads (45%) | called by muse, mutect2, varscan2
- GLA | c.630C>A p.P210= | Silent (SNP) | VAF 370/1046 reads (35%) | catalogued as COSV54509664; called by muse, mutect2, varscan2
- GLDC | c.2601G>A p.T867= | Silent (SNP) | VAF 401/1047 reads (38%) | catalogued as rs371678175; called by muse, mutect2, varscan2
- GRIN3B | c.1551C>T p.V517= | Silent (SNP) | VAF 57/145 reads (39%) | catalogued as rs767260421, COSV52264196; called by muse, mutect2, varscan2
- GRM2 | c.1920C>T p.G640= | Silent (SNP) | VAF 340/636 reads (53%) | called by muse, mutect2, varscan2
- HELZ | c.5223G>A p.S1741= | Silent (SNP) | VAF 296/742 reads (40%) | catalogued as rs977086858, COSV100698704; called by muse, mutect2, varscan2
- HELZ2 | c.7438C>T p.L2480= (on ENST00000467148 / NM_001037335.2; = p.L1911= on NM_033405.3) | Silent (SNP) | VAF 265/718 reads (37%) | catalogued as rs941343696; called by muse, mutect2, varscan2
- HENMT1 | c.861G>A p.L287= | Silent (SNP) | VAF 353/874 reads (40%) | catalogued as rs766218342; called by muse, mutect2, varscan2
- HES1 | c.717G>A p.A239= | Silent (SNP) | VAF 148/315 reads (47%) | catalogued as rs764280631; called by muse, mutect2, varscan2
- KAZN | c.1704C>T p.N568= | Silent (SNP) | VAF 217/587 reads (37%) | catalogued as rs756365309; called by muse, mutect2, varscan2
- KCNG1 | c.531G>A p.A177= | Silent (SNP) | VAF 215/530 reads (41%) | catalogued as rs140916173; called by muse, mutect2, varscan2
- KCNG4 | c.1170C>T p.Y390= | Silent (SNP) | VAF 275/744 reads (37%) | catalogued as rs751055675; called by muse, mutect2, varscan2
- KCNQ1 | c.867C>T p.N289= | Silent (SNP) | VAF 464/1083 reads (43%) | catalogued as rs1262523905, COSV99328068; called by muse, mutect2, varscan2
- KCNQ5 | c.495C>T p.F165= | Silent (SNP) | VAF 607/1439 reads (42%) | catalogued as rs777287414, COSV59650187; called by muse, mutect2, varscan2
- KHDRBS3 | c.783G>A p.P261= | Silent (SNP) | VAF 353/929 reads (38%) | catalogued as rs577272565, COSV100878417; called by muse, mutect2, varscan2
- KRTAP5-5 | c.57C>T p.S19= | Silent (SNP) | VAF 419/1463 reads (29%) | catalogued as rs1337794192, COSV68784295; called by muse, mutect2
- LAMA3 | c.4668G>A p.P1556= | Silent (SNP) | VAF 462/1170 reads (39%) | catalogued as rs200532263, COSV58074745; called by muse, mutect2, varscan2
- LCN6 | c.309C>T p.G103= | Silent (SNP) | VAF 85/251 reads (34%) | catalogued as rs372944293; called by muse, mutect2, varscan2
- LTBP3 | c.3318C>T p.C1106= | Silent (SNP) | VAF 264/662 reads (40%) | catalogued as rs1224821827; called by muse, mutect2, varscan2
- MAD1L1 | c.360G>A p.A120= | Silent (SNP) | VAF 277/618 reads (45%) | catalogued as rs755685953, COSV56231148; called by muse, mutect2, varscan2
- MAN2B1 | c.2631C>T p.A877= | Silent (SNP) | VAF 208/491 reads (42%) | called by muse, mutect2, varscan2
- MAP3K5 | c.2574C>T p.Y858= | Silent (SNP) | VAF 375/910 reads (41%) | catalogued as rs747262517, COSV62887415; called by muse, mutect2, varscan2
- MAPK3 | c.1119C>T p.P373= | Silent (SNP) | VAF 170/404 reads (42%) | catalogued as rs766545784, COSV53772589; called by muse, mutect2, varscan2
- MDGA1 | c.1683G>A p.S561= | Silent (SNP) | VAF 349/819 reads (43%) | called by muse, mutect2, varscan2
- MED15 | c.843G>A p.P281= | Silent (SNP) | VAF 299/780 reads (38%) | catalogued as rs201001092; called by muse, mutect2, varscan2
- MRGPRF | c.291G>A p.A97= | Silent (SNP) | VAF 206/524 reads (39%) | catalogued as rs1454275178, COSV57996028; called by muse, mutect2, varscan2
- MUC5B | c.4932G>A p.P1644= | Silent (SNP) | VAF 181/403 reads (45%) | catalogued as rs749776295, COSV101500224; called by muse, mutect2, varscan2
- MYPOP | c.321C>T p.D107= | Silent (SNP) | VAF 94/234 reads (40%) | called by muse, mutect2, varscan2
- NACC2 | c.615G>A p.A205= | Silent (SNP) | VAF 156/392 reads (40%) | catalogued as rs1386787122; called by muse, mutect2, varscan2
- NADSYN1 | c.2028C>T p.Y676= | Silent (SNP) | VAF 394/986 reads (40%) | called by muse, mutect2, varscan2
- NALCN | c.618C>T p.H206= | Silent (SNP) | VAF 288/414 reads (70%) | catalogued as rs1172867534; called by muse, mutect2, varscan2
- NEFM | c.2634C>T p.T878= | Silent (SNP) | VAF 294/626 reads (47%) | catalogued as rs151082365; called by muse, mutect2, varscan2
- NETO2 | c.177G>A p.S59= | Silent (SNP) | VAF 446/1110 reads (40%) | catalogued as rs143382306; called by muse, mutect2, varscan2
- NHSL1 | c.4311C>T p.S1437= | Silent (SNP) | VAF 418/1044 reads (40%) | catalogued as rs1347785764; called by muse, mutect2, varscan2
- NHSL1 | c.2580G>A p.S860= | Silent (SNP) | VAF 318/747 reads (43%) | catalogued as rs776764448; called by muse, mutect2, varscan2
- NTSR1 | c.834G>A p.T278= | Silent (SNP) | VAF 198/500 reads (40%) | catalogued as rs774735789; called by muse, mutect2, varscan2
- NWD2 | c.4050C>T p.I1350= | Silent (SNP) | VAF 325/793 reads (41%) | catalogued as rs767955118; called by muse, mutect2, varscan2
- OBSCN | c.1584C>T p.S528= | Silent (SNP) | VAF 291/791 reads (37%) | catalogued as rs754795176, COSV52776332; called by muse, mutect2, varscan2
- OCSTAMP | c.1179C>T p.P393= | Silent (SNP) | VAF 229/521 reads (44%) | catalogued as rs894381723; called by muse, mutect2, varscan2
- OR6X1 | c.478C>T p.L160= | Silent (SNP) | VAF 73/722 reads (10%) | called by muse, mutect2
- PCDH19 | c.1815C>T p.Y605= | Silent (SNP) | VAF 35/1159 reads (3%) | catalogued as rs1057521256; ClinVar: likely benign; called by muse, mutect2
- PCSK1N | c.333C>T p.R111= | Silent (SNP) | VAF 183/466 reads (39%) | called by muse, mutect2, varscan2
- PDLIM7 | c.369G>A p.P123= | Silent (SNP) | VAF 235/633 reads (37%) | catalogued as rs1317883999; called by muse, mutect2, varscan2
- PEAK3 | c.12G>A p.P4= | Silent (SNP) | VAF 189/453 reads (42%) | catalogued as rs147999963; called by muse, mutect2, varscan2
- PIF1 | c.1308C>T p.N436= | Silent (SNP) | VAF 310/804 reads (39%) | catalogued as rs752487060; called by muse, mutect2, varscan2
- PIGZ | c.156G>A p.P52= | Silent (SNP) | VAF 71/948 reads (7%) | catalogued as rs202148620; called by muse, mutect2
- PKD1L2 | c.2445C>T p.C815= | Silent (SNP) | VAF 195/479 reads (41%) | called by muse, mutect2, varscan2
- PLEKHH1 | c.3261C>T p.V1087= | Silent (SNP) | VAF 233/550 reads (42%) | catalogued as rs765543779; called by muse, mutect2, varscan2
- PLEKHM3 | c.1764C>T p.N588= | Silent (SNP) | VAF 243/484 reads (50%) | catalogued as rs749955829, COSV66815322; called by muse, mutect2, varscan2
- POFUT2 | c.1092C>T p.D364= | Silent (SNP) | VAF 347/803 reads (43%) | catalogued as rs376389566; called by muse, mutect2, varscan2
- POLM | c.879C>T p.S293= | Silent (SNP) | VAF 314/857 reads (37%) | catalogued as rs762468461; called by muse, mutect2, varscan2
- PRCP | c.249T>C p.G83= | Silent (SNP) | VAF 384/821 reads (47%) | called by muse, mutect2, varscan2
- PRDM15 | c.2280C>T p.I760= | Silent (SNP) | VAF 165/476 reads (35%) | catalogued as rs1568918991; called by muse, mutect2, varscan2
- PRPF18 | c.753G>A p.T251= | Silent (SNP) | VAF 268/727 reads (37%) | catalogued as rs775349638; called by muse, mutect2, varscan2
- PRR5L | c.9C>T p.R3= | Silent (SNP) | VAF 278/803 reads (35%) | catalogued as rs768861738; called by muse, mutect2
- RASIP1 | c.870G>A p.A290= | Silent (SNP) | VAF 300/806 reads (37%) | catalogued as rs1435928094; called by muse, mutect2, varscan2
- RNPEPL1 | c.1494C>T p.S498= | Silent (SNP) | VAF 88/427 reads (21%) | catalogued as rs141937747; called by muse, mutect2, varscan2
- SCLY | c.141G>A p.T47= (on ENST00000651534; = p.T39= on NM_016510.7) | Silent (SNP) | VAF 44/912 reads (5%) | catalogued as rs1452316566, COSV99616332; called by muse, mutect2
- SHANK2 | c.2673G>A p.P891= | Silent (SNP) | VAF 98/256 reads (38%) | catalogued as rs782595165; called by muse, mutect2, varscan2
- SHC2 | c.789C>T p.Y263= | Silent (SNP) | VAF 146/404 reads (36%) | catalogued as rs760036602; called by muse, mutect2, varscan2
- SLC22A14 | c.1476C>T p.A492= | Silent (SNP) | VAF 314/602 reads (52%) | catalogued as rs764775912; called by muse, mutect2, varscan2
- SLC23A2 | c.609C>T p.H203= | Silent (SNP) | VAF 378/894 reads (42%) | called by muse, mutect2, varscan2
- SLC26A9 | c.627G>A p.T209= | Silent (SNP) | VAF 267/565 reads (47%) | catalogued as rs146088150; called by muse, mutect2, varscan2
- SLC39A8 | c.600T>C p.V200= | Silent (SNP) | VAF 381/1029 reads (37%) | called by muse, mutect2, varscan2
- SLC41A2 | c.840T>C p.S280= | Silent (SNP) | VAF 293/744 reads (39%) | called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 52/1320 reads (4%) | called by muse, mutect2
- SLIT2 | c.430A>C p.R144= | Silent (SNP) | VAF 36/1145 reads (3%) | called by muse, mutect2
- SNRNP25 | c.345C>T p.Y115= (on ENST00000383018; = p.Y106= on NM_024571.4) | Silent (SNP) | VAF 256/678 reads (38%) | catalogued as rs779464960; called by muse, mutect2, varscan2
- SPATA24 | c.84T>G p.S28= | Silent (SNP) | VAF 42/892 reads (5%) | called by muse, mutect2
- SWI5 | c.270C>T p.S90= | Silent (SNP) | VAF 193/549 reads (35%) | catalogued as rs1217156886, COSV60792619; called by muse, mutect2, varscan2
- TBC1D22A | c.135G>A p.T45= | Silent (SNP) | VAF 412/1008 reads (41%) | catalogued as rs781486523; called by muse, mutect2, varscan2
- TDRD12 | c.198T>C p.Y66= | Silent (SNP) | VAF 141/405 reads (35%) | called by muse, mutect2, varscan2
- THEG | c.78C>T p.D26= | Silent (SNP) | VAF 214/479 reads (45%) | catalogued as rs371471812; called by muse, mutect2, varscan2
- TMEM233 | c.204C>T p.N68= | Silent (SNP) | VAF 419/936 reads (45%) | catalogued as rs1188243542; called by muse, mutect2, varscan2
- TMEM30B | c.1044C>T p.D348= | Silent (SNP) | VAF 214/534 reads (40%) | catalogued as rs1268104840; called by muse, mutect2, varscan2
- TRIM54 | c.906G>A p.P302= (on ENST00000380075 / NM_187841.3; = p.P344= on NM_032546.4) | Silent (SNP) | VAF 298/706 reads (42%) | catalogued as rs759003803; called by muse, mutect2, varscan2
- TRIM72 | c.1290C>T p.S430= | Silent (SNP) | VAF 190/472 reads (40%) | catalogued as rs1359276200, COSV59066918; called by muse, mutect2, varscan2
- UHMK1 | c.357G>A p.S119= | Silent (SNP) | VAF 529/1218 reads (43%) | called by muse, mutect2, varscan2
- URB1 | c.1614G>A p.P538= | Silent (SNP) | VAF 279/640 reads (44%) | catalogued as rs745354769; called by muse, mutect2, varscan2
- VPS37A | c.132C>T p.A44= | Silent (SNP) | VAF 251/702 reads (36%) | catalogued as rs140443698; called by muse, mutect2, varscan2
- Z83844.2 | c.1539G>A p.S513= | Silent (SNP) | VAF 202/512 reads (39%) | catalogued as rs550129760; called by muse, mutect2, varscan2
- ZBTB1 | c.1494C>T p.S498= | Silent (SNP) | VAF 327/780 reads (42%) | catalogued as rs748192936, COSV100704145; called by muse, mutect2, varscan2
- ZC3HAV1 | c.873C>T p.D291= | Silent (SNP) | VAF 203/488 reads (42%) | catalogued as rs756401135, COSV99648719; called by muse, mutect2, varscan2
- ZFR2 | c.993G>A p.A331= | Silent (SNP) | VAF 145/419 reads (35%) | catalogued as rs960451142, COSV99507694; called by muse, mutect2, varscan2
- AC233702.8 | chr17:21551341 C>T | 5'Flank (SNP) | VAF 251/649 reads (39%) | catalogued as rs1173137654; called by muse, mutect2, varscan2
- ALDH16A1 | c.1939-41G>A | Intron (SNP) | VAF 63/130 reads (48%) | catalogued as rs1051696093; called by muse, mutect2, varscan2
- ALOX5 | c.1674+91G>A | Intron (SNP) | VAF 45/90 reads (50%) | catalogued as COSV65553977; called by muse, mutect2, varscan2
- AMDHD2 | c.*10C>T | 3'UTR (SNP) | VAF 164/397 reads (41%) | catalogued as rs778235303; called by muse, mutect2, varscan2
- ANKRD13D | c.*466G>A | 3'UTR (SNP) | VAF 372/906 reads (41%) | catalogued as rs981967443, COSV57752459, COSV57752853; called by muse, mutect2, varscan2
- AP3D1 | c.2602-20C>T | Intron (SNP) | VAF 154/406 reads (38%) | catalogued as rs775648858; called by muse, mutect2, varscan2
- AP5Z1 | c.512-67G>T | Intron (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- ATAD3B | c.*370C>T | 3'UTR (SNP) | VAF 140/450 reads (31%) | catalogued as rs746536347; called by muse, mutect2, varscan2
- BTF3 | c.574+9G>A | Intron (SNP) | VAF 319/802 reads (40%) | catalogued as rs756986460; called by muse, mutect2, varscan2
- CHD2 | c.62+40del | Intron (DEL) | VAF 130/356 reads (37%) | catalogued as rs769211092; called by mutect2, varscan2
- CHD8 | c.4063-80del | Intron (DEL) | VAF 54/153 reads (35%) | catalogued as rs375753246; called by mutect2, varscan2
- CLDN23 | c.*22C>T | 3'UTR (SNP) | VAF 139/302 reads (46%) | catalogued as rs922252219, COSV67731659; called by muse, mutect2, varscan2
- CNOT2 | c.1290+32C>T | Intron (SNP) | VAF 158/387 reads (41%) | called by muse, mutect2, varscan2
- COA4 | c.*10C>T | 3'UTR (SNP) | VAF 68/180 reads (38%) | called by muse, mutect2, varscan2
- CPE | c.*69del | 3'UTR (DEL) | VAF 64/180 reads (36%) | catalogued as rs890628729; called by mutect2, varscan2
- CSNK1G2 | c.*71C>T | 3'UTR (SNP) | VAF 46/91 reads (51%) | catalogued as rs768545852; called by muse, mutect2, varscan2
- CSPG4 | c.-20C>A | 5'UTR (SNP) | VAF 16/218 reads (7%) | called by muse, mutect2
- CTU1 | c.-4C>T | 5'UTR (SNP) | VAF 81/162 reads (50%) | called by muse, mutect2, varscan2
- DRC7 | c.2085+61G>A | Intron (SNP) | VAF 27/65 reads (42%) | catalogued as rs374206219; called by muse, mutect2, varscan2
- DST | chr6:56458951 G>A | 3'Flank (SNP) | VAF 91/226 reads (40%) | catalogued as rs1003347545, COSV99760910; called by muse, mutect2, varscan2
- EEF1D | c.189+28G>A | Intron (SNP) | VAF 125/346 reads (36%) | catalogued as rs551982323; called by muse, mutect2, varscan2
- EIF3B | c.2155-566G>A | Intron (SNP) | VAF 132/1071 reads (12%) | called by muse, varscan2
- FCGR2A | c.*9G>A | 3'UTR (SNP) | VAF 290/1331 reads (22%) | catalogued as rs200653207; called by muse, mutect2, varscan2
- FGF19 | c.*54C>T | 3'UTR (SNP) | VAF 52/125 reads (42%) | catalogued as rs886599661, COSV99594363; called by muse, mutect2, varscan2
- FNTB | c.*60C>T | 3'UTR (SNP) | VAF 28/93 reads (30%) | catalogued as rs181587610; called by muse, mutect2, varscan2
- HAGHL | c.*202G>A | 3'UTR (SNP) | VAF 184/469 reads (39%) | catalogued as rs765933247; called by muse, mutect2, varscan2
- HIPK2 | c.*72C>T | 3'UTR (SNP) | VAF 108/223 reads (48%) | catalogued as rs534108975, COSV101301644; called by muse, mutect2, varscan2
- IL24 | c.*96C>T | 3'UTR (SNP) | VAF 36/103 reads (35%) | catalogued as rs147017417; called by muse, mutect2, varscan2
- KCP | c.835-25C>T | Intron (SNP) | VAF 95/331 reads (29%) | catalogued as rs747426211; called by muse, mutect2, varscan2
- LEPR | c.-21+2433del | Intron (DEL) | VAF 283/816 reads (35%) | called by mutect2, varscan2
- LHCGR | c.*53del | 3'UTR (DEL) | VAF 72/184 reads (39%) | catalogued as rs200887026; called by mutect2, varscan2
- LINC01273 | n.886G>A | RNA (SNP) | VAF 65/137 reads (47%) | called by muse, mutect2, varscan2
- LRCH4 | c.*1051G>A | 3'UTR (SNP) | VAF 142/351 reads (40%) | catalogued as rs1482888115; called by muse, mutect2, varscan2
- LRP5L | n.336G>A | RNA (SNP) | VAF 264/605 reads (44%) | catalogued as rs748139243; called by muse, mutect2, varscan2
- MED13L | c.4339-44G>A | Intron (SNP) | VAF 105/220 reads (48%) | catalogued as rs892039872; called by muse, mutect2, varscan2
- MLF2 | c.50+58G>A | Intron (SNP) | VAF 11/299 reads (4%) | called by muse, mutect2
- MMP17 | c.*8C>T | 3'UTR (SNP) | VAF 172/447 reads (38%) | called by muse, mutect2, varscan2
- MYOCD | chr17:12763697 G>T | 3'Flank (SNP) | VAF 228/518 reads (44%) | called by muse, mutect2, varscan2
- NSFL1C | c.*3G>A | 3'UTR (SNP) | VAF 164/404 reads (41%) | catalogued as rs1359186815, COSV99401363; called by muse, varscan2
- P3H4 | c.787+76C>T | Intron (SNP) | VAF 96/175 reads (55%) | catalogued as rs111439094; called by muse, mutect2, varscan2
- PAQR6 | c.760+11G>A | Intron (SNP) | VAF 281/729 reads (39%) | catalogued as rs1429791982; called by muse, mutect2, varscan2
- PCYT2 | c.179-60C>A | Intron (SNP) | VAF 82/206 reads (40%) | called by muse, mutect2, varscan2
- PDE6A | c.*26C>T | 3'UTR (SNP) | VAF 167/368 reads (45%) | catalogued as rs749365205; called by muse, mutect2, varscan2
- PHLDB1 | c.3121+15C>T | Intron (SNP) | VAF 127/264 reads (48%) | catalogued as rs377018710; called by muse, mutect2, varscan2
- PKD1 | c.3162-10G>A | Intron (SNP) | VAF 204/590 reads (35%) | catalogued as rs749582224; called by muse, mutect2, varscan2
- PPIE | c.*27C>T | 3'UTR (SNP) | VAF 191/431 reads (44%) | catalogued as rs778985859; called by muse, mutect2, varscan2
- PRKG1 | c.1963-19del | Intron (DEL) | VAF 256/592 reads (43%) | catalogued as rs145115489; ClinVar: likely benign; called by mutect2, varscan2
- RAB11FIP1 | c.3525-73G>A | Intron (SNP) | VAF 82/195 reads (42%) | catalogued as rs1281432399; called by muse, mutect2, varscan2
- RAB18 | c.187-892C>T | Intron (SNP) | VAF 344/835 reads (41%) | catalogued as rs1469669886; called by muse, mutect2, varscan2
- RHBDL1 | c.*17G>A | 3'UTR (SNP) | VAF 144/345 reads (42%) | called by muse, mutect2, varscan2
- SOCS3 | c.-70C>T | 5'UTR (SNP) | VAF 40/73 reads (55%) | called by muse, mutect2, varscan2
- SPDYC | c.-10C>T | 5'UTR (SNP) | VAF 208/540 reads (39%) | catalogued as rs201918813; called by muse, mutect2, varscan2
- SRPX | c.*3T>C | 3'UTR (SNP) | VAF 197/461 reads (43%) | called by muse, mutect2, varscan2
- SUGP1 | c.206+15G>A | Intron (SNP) | VAF 157/353 reads (44%) | called by muse, mutect2, varscan2
- TCIRG1 | c.1463+21C>T | Intron (SNP) | VAF 177/416 reads (43%) | catalogued as rs371898025; called by muse, mutect2, varscan2
- TKTL1 | c.*28C>A | 3'UTR (SNP) | VAF 173/430 reads (40%) | called by muse, mutect2, varscan2
- TMPRSS5 | c.*95C>T | 3'UTR (SNP) | VAF 207/433 reads (48%) | catalogued as rs547367520, COSV100244878; called by muse, mutect2, varscan2
- TRIM15 | c.-20G>A | 5'UTR (SNP) | VAF 130/259 reads (50%) | catalogued as rs1205890022, COSV100938844; called by muse, mutect2, varscan2
- UBA5 | c.685-26del | Intron (DEL) | VAF 207/492 reads (42%) | catalogued as rs59956066; called by mutect2, varscan2
- WASHC5 | c.-8G>A | 5'UTR (SNP) | VAF 344/884 reads (39%) | catalogued as rs776534136, COSV59196088; called by muse, mutect2, varscan2
- WDR90 | c.4145+78G>A | Intron (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- XPA | c.*87del | 3'UTR (DEL) | VAF 62/117 reads (53%) | catalogued as rs750807332; called by mutect2, varscan2
- YBX2 | c.335+68C>T | Intron (SNP) | VAF 80/178 reads (45%) | catalogued as rs1334578758; called by muse, mutect2, varscan2
- ZNF516 | chr18:76496632 C>T | 5'Flank (SNP) | VAF 160/387 reads (41%) | catalogued as rs1187375692; called by muse, mutect2, varscan2
